Surgical pathology report (de-identified scan), TCGA case TCGA-TS-A7PB, project TCGA-MESO (Mesothelioma), tissue source site University of Pennsylvania, specimen TCGA-TS-A7PB-01A (Primary Tumor).

[page 1 of 5]
Age: years Sex: Male

Date Printed:
Date Collected :
Date Received:
Accession N
Physician:
Copy to:

S u r g i c a l P a t h o l o g y R e p o r t

ICD O-3
Mesothelioma, liphasia NOS
9053/3
Site @ Pleura C38.4
9/24/13

Clinical Information

year old male with mesothelioma, Left Thoracotomy, Pleurectomy, PDT, Bronchoscopy

Final Diagnosis

1. RIB:

Section of rib with bone marrow, no tumor seen.
Fibroadipose tissue and skeletal muscle, no tumor seen.

2. LYMPH NODE, STATION 10:

One fragment of lymph node, no tumor seen (0/1).

3. LYMPH NODE, STATION 8:

Two out of two lymph node showing small focus of metastatic mesothelioma (2/2), confirmed by CK5/6 and calretinin immunostains.

4. LYMPH NODE, STATION 6:

Three out of four lymph nodes showing metastatic mesothelioma (3/4).

5. LYMPH NODE, PERICARDIAL:

Two out of two lymph nodes showing metastatic mesothelioma (2/2).

6. LYMPH NODE, LEVEL 7:

One lymph nodes showing metastatic mesothelioma (1/1).

7. LYMPH NODE, PHRENIC NODE:

One lymph node, no tumor seen (0/1).

8. LYMPH NODE, ANTERIOR HILAR:

One lymph node, no tumor seen (0/1).

9. LYMPH NODE, LEVEL 2:

One out of two lymph nodes showing metastatic mesothelioma (1/2).

10. LYMPH NODE, LEVEL 5:

One out of four lymph nodes showing metastatic mesothelioma (1/4).
Adipose tissue with focal presence of mesothelioma, epithelioid type, confirmed by CK5/6 immunostain.

11. PHRENIC NERVE:

Peripheral nerve fibers, no tumor seen.

Name
MRN

[page 2 of 5]
Name: [REDACTED]
MRN: [REDACTED]
Age: [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed:
Date Collected
Date Received
Accession No:
Physician:
Copy to:

S u r g i c a l P a t h o l o g y R e p o r t

FibroadiPOSE tissue with focal presence of mesothelioma, epithelioid type, confirmed by CK5/6 and calretinin immunostains.

12. POSTERIOR INTERCOSTAL:

Two out of two lymph nodes showing metastatic mesothelioma (2/2).

13. PLEURA:

Biphasic malignant mesothelioma (~90% epithelioid and ~10% sarcomatoid) with focal necrosis.
Tumor involves skeletal muscle and superficial lung tissue.
See synoptic report.

14. PERICARDIAL MASS:

Biphasic malignant mesothelioma (~20% epithelioid and ~80% sarcomatoid) with focal necrosis.
Tumor involves underlying superficial lung tissue.
Inked pericardial margin is free of tumor.
See comment and synoptic report.

The case material was reviewed and the report verified by:
(Electronic signature)
Verification Date:

Note

Immunohistochemical stains are performed with adequate controls (see disclaimer). The tumor cells are positive for CK5/6, calretinin, D2-40 and WT-1; the tumor cells are negative for TTF-1 and Moc31.
This immunoprofile supports the above diagnosis.

Slides 10A, 14B and 14D reviewed with

Disclaimer:

The above in-vitro IHC tests may have used reagents labeled for IVD (In Vitro Diagnostic Use), IUO (Investigational Use Only) and/or RUO (Research Use Only) and have not been cleared or approved by the U.S Food and Drug Administration. However, the FDA has determined that such clearance or approval is not necessary for ASR class I tests intended to provide pathologists with adjunctive information to assist their morphologic evaluation. The tests using IUO or IUO reagents were developed and their performance characteristics were validated for diagnostic use by the

This laboratory is regulated under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical tests. These Class I ASR tests are not intended to provide diagnostic, prognostic, predictive or therapeutic information that is not directly confirmed by routine histopathologic internal or external control specimens.

Name: [REDACTED]
MRN: [REDACTED]

[page 3 of 5]
Name: [REDACTED]
MRN: [REDACTED]
Age: [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed: [REDACTED]
Date Collected: [REDACTED]
Date Received: [REDACTED]
Accession No.: [REDACTED]
Physician: [REDACTED]
Copy to: [REDACTED]

S u r g i c a l P a t h o l o g y R e p o r t

Synoptic Report

Site:

Left

Histologic Type

Biphasic mesothelioma

Margins

Cannot be assessed

Lymph nodes

Specify: Number examined: 20
Number involved: 12

Pathologic Staging: pT3N2Mx

Gross Description

The specimen is received in 14 parts in formalin in a container labeled with the patient's name and medical record number.

Specimen #1 received in formalin labeled "Rib" and consists of two ragged and irregular fragments of tan-white to tan-brown bone, grossly consistent with portions of rib, measuring 1.1 and 1.8 cm in greatest dimension. The largest fragment is serially sectioned and the specimen is submitted entirely in cassette 1A following decalcification.

Specimen #2 received in formalin labeled "Station 10" and consists of a 0.8 x 0.5 x 0.2 cm gray-black, irregular soft tissue fragment, which is submitted in toto in cassette 2A.

Specimen #3 received in formalin labeled "Station 8" and consists of two tan-yellow, irregular to nodular soft tissue fragments measuring 0.7 and 0.8 cm in greatest dimension. The more nodular fragment is bisected to reveal tan-white, dense cut surfaces. The larger fragment is submitted entirely in cassette 3A and the smaller, intact fragment is submitted in toto in cassette 3B.

Specimen #4 received in formalin labeled "Station 6" and consists of four gray-black to tan-yellow, irregular to vaguely nodular soft tissue fragments ranging from 0.8 to 1.5 cm in greatest dimension. The two larger fragments are bisected and submitted entirely in cassettes 4A and 4B, respectively, and the remaining two soft tissue fragments are submitted in toto in cassette 4C.

Specimen #5 received in formalin labeled "Pericardial Node" and consists of two tan-yellow to tan-white, irregular to nodular soft tissue fragments each measuring 1.2 cm in greatest dimension. Each fragment is bisected to reveal tan-white, dense cut surfaces. The specimen is submitted entirely in cassettes 5A and 5B, respectively.

Name: [REDACTED]
MRN: [REDACTED]

[page 4 of 5]
Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed: [REDACTED]
Date Collected: [REDACTED]
Date Received: [REDACTED]
Accession No: [REDACTED]
Physician: [REDACTED]
Copy to: [REDACTED]

S u r g i c a l P a t h o l o g y R e p o r t

Specimen #6 received in formalin labeled "Level 7" and consists of a 1.5 x 0.9 x 0.8 cm tan-gray, nodular soft tissue fragment, which is bisected to reveal tan-white to gray-black, firm cut surfaces. The specimen is submitted entirely in cassette 6A.

Specimen #7 received in formalin labeled "Phrenic Node" and consists of a 2.3 x 2.2 x 0.8 cm tan-yellow to gray-black, nodular soft tissue fragment, which is bisected to reveal gray-black to red-brown, dense cut surfaces. The specimen is submitted entirely in cassette 7A.

Specimen #8 labeled "Anterior Hilar Node" and consists of a 2.0 x 1.3 x 1.1 cm gray-black, nodular soft tissue fragment, which is bisected to reveal gray-black to red-brown, dense cut surfaces. The specimen is submitted entirely in cassette 8A.

Specimen #9 received in formalin labeled "Level 2" and consists of two tan-yellow to gray-black, irregular to nodular soft tissue fragments measuring 0.8 and 1.5 cm in greatest dimension. The larger fragment is bisected and the specimen is submitted entirely in cassette 9A.

Specimen #10 received in formalin labeled "Level 5" and consists of two grey-black to tan-yellow, nodular soft tissue fragments measuring 1.3 and 2.3 cm in greatest dimension. The larger fragment is bisected to reveal tan-yellow to red-brown, dense cut surfaces. The larger fragment is submitted entirely in cassette 10A, and the remainder of the specimen is submitted in toto in cassette 10B.

Specimen #11 received in formalin labeled "Phrenic Nerve" and consists of a 2.5 x 0.8 x 0.3 cm tan-white to tan-yellow, irregular to vaguely cylindrical soft tissue fragment, which is submitted in toto in cassette 11A.

Specimen #12 received in formalin labeled "Posterior Intercostal" and consists of two tan-yellow to gray-black, irregular soft tissue fragments measuring 0.6 cm in greatest dimension each. The specimen is submitted in toto in cassette 12A.

Specimen #13 received in formalin labeled "Pleura" and consists of a 638.4 g, 21.5 x 18.4 x 7.5 cm ragged and irregular portion of tan-yellow to tan-white, rubbery soft tissue, grossly consistent with a portion of pleura. There are areas of red-brown, rubbery muscle and tan-yellow, lobulated adipose tissue attached. Focal areas are diffusely thickened and reveal tan-white, dense cut surfaces, measuring up to 19.0 cm in greatest dimension. Focal areas are calcified. Representative sections are submitted in cassettes 13A through 13F.

Specimen #14 received in formalin labeled "Pericardial Mass" and consists of a 4.5 x 3.6 x 2.1 cm irregular portion of tan to tan-yellow, cauterized, firm soft tissue. One surface is covered by a 3.9 x 3.5 cm portion of tan-pink to tan-white, glistening, focally ragged soft tissue which per the surgeon denotes the deep margin facing the heart (inked black). The remaining surface displays a portion which was removed by the surgeon for research purposes. Sectioning reveals a 3.9 x 2.9 x 1.8 cm tan-white to tan-yellow, firm mass which grossly abuts the black inked deep margin facing the heart. There is only a small amount of tan-yellow to tan-white, uninvolved soft tissue identified. Representative sections are submitted in

Name: [REDACTED]
MRN: [REDACTED]

[page 5 of 5]
Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED] Age [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed: [REDACTED]
Date Collected [REDACTED]
Date Received [REDACTED]
Accession No. [REDACTED]
Physician: [REDACTED]
Copy to: [REDACTED]

S u r g i c a l P a t h o l o g y R e p o r t

cassettes 14A through 14E.

Dictated by:

Pathologist(s)

Name: [REDACTED]
MRN: [REDACTED]

Page 5 of 5

lw 8/27/13
CNR 8/26/13

Source: NCI Genomic Data Commons file 9dc84dd0-606e-4e1a-9d1e-f0d2f4c38fa5 (TCGA-TS-A7PB.10F97F63-EE6F-448D-98E1-8AAA21F55753.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).